Somatic mutation profile of cancer-model specimen HCM-SANG-0274-C18-85A (3D Organoid; aliquot HCM-SANG-0274-C18-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0274-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0274-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ceb5eba2-5203-4291-8c44-bf31b3e7c5c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0274-C18-10A (Blood Derived Normal), aliquot HCM-SANG-0274-C18-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad939d0e-3c0e-4822-b338-867184377d34

The open-access MAF lists 170 somatic variants for this specimen: 127 protein-altering or splice-affecting, 37 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 37, Nonsense Mutation 10, Intron 4, Frame Shift Del 4, Frame Shift Ins 3, Splice Region 1, RNA 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 140/140 reads (100%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 351/351 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.3682G>T p.E1228* (on ENST00000272895 / NM_173076.3; = p.E910* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 69/317 reads (22%) | catalogued as COSV99787894; called by muse, mutect2, varscan2
- ADAMTS20 | c.5149del p.E1717Kfs*4 | Frame Shift Del (DEL) | VAF 28/207 reads (14%) | catalogued as COSV67138046; called by mutect2, pindel, varscan2
- AFG3L2 | c.2167G>A p.V723M | Missense Mutation (SNP) | VAF 70/193 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs139469785; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- AL121899.2 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 190/465 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1050145837, COSV67350372; called by muse, mutect2
- ALOX12B | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 26/562 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1340831345; called by muse, mutect2
- ANKRD60 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 137/717 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs899988816, COSV64518559; called by muse, mutect2, varscan2
- COL11A1 | c.5362T>C p.F1788L | Missense Mutation (SNP) | VAF 117/248 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV100616746, COSV62177757; called by muse, mutect2, varscan2
- CYP2W1 | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 43/488 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as rs753529686; called by muse, mutect2
- DAB2IP | c.2455C>T p.R819W (on ENST00000408936; = p.R791W on NM_032552.3) | Missense Mutation (SNP) | VAF 49/774 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs749134055; called by muse, mutect2
- DGKQ | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 188/513 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs756554134, COSV56619852; called by muse, mutect2, varscan2
- DLGAP4 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 269/1462 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs371602287, COSV59414211, COSV59416040; called by muse, mutect2, varscan2
- DMRTA1 | c.893C>G p.S298C | Missense Mutation (SNP) | VAF 122/270 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as COSV57924016; called by muse, mutect2, varscan2
- DNAJC5 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 196/1088 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs770758533; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EBF3 | c.1228G>A p.E410K (on ENST00000355311 / NM_001375392.1; = p.E401K on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 176/400 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.703); catalogued as rs1490116339; called by muse, mutect2, varscan2
- EPHB1 | c.1651G>A p.V551M | Missense Mutation (SNP) | VAF 139/344 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs368240835; called by muse, mutect2, varscan2
- ERBB4 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 113/386 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as rs569995088, COSV53501451; called by muse, mutect2, varscan2
- FAM163A | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 354/682 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs772845482; called by muse, mutect2, varscan2
- FILIP1L | c.2254C>T p.Q752* (on ENST00000354552 / NM_182909.3; = p.Q512* on NM_014890.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/422 reads (5%) | catalogued as COSV100496419; called by muse, mutect2
- FOXL3 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 134/372 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs758210197; called by muse, mutect2, varscan2
- FYB1 | c.2235A>C p.K745N (on ENST00000351578 / NM_199335.5; = p.K791N on NM_001465.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 159/345 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100684815; called by muse, mutect2, varscan2
- FYCO1 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 131/263 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761031320; called by muse, mutect2, varscan2
- GABRB3 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 223/371 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV54665513; called by muse, mutect2, varscan2
- GABRG1 | c.782C>A p.T261K | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs1000210963, COSV54962111; called by muse, mutect2, varscan2
- GRID2 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 164/255 reads (64%) | catalogued as rs757352968, COSV99939771; called by muse, mutect2, varscan2
- H1-7 | c.477G>T p.Q159H | Missense Mutation (SNP) | VAF 314/720 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.071); catalogued as rs1013601087, COSV58602748; called by muse, mutect2
- H2AC1 | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 153/494 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs200120159, COSV51238833; called by muse, mutect2, varscan2
- IGDCC4 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 377/377 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as rs753195920; called by muse, mutect2, varscan2
- IMPG2 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 48/387 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV99515675; called by muse, mutect2, varscan2
- IRF4 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 300/878 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV66704361; called by muse, mutect2, varscan2
- KIF21B | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 129/282 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759281080, COSV100145210; called by muse, mutect2, varscan2
- KISS1 | c.394G>T p.G132C | Missense Mutation (SNP) | VAF 201/455 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs977742222; called by muse, mutect2, varscan2
- KLK5 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 143/301 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60449568; called by muse, mutect2, varscan2
- KMT2D | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 23/296 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as rs770105193, COSV56494847; called by muse, mutect2
- KRBA1 | c.3005C>T p.P1002L | Missense Mutation (SNP) | VAF 633/813 reads (78%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs757132453; called by muse, mutect2, varscan2
- LRRC8C | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 184/381 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as rs750251531; called by muse, mutect2, varscan2
- MMUT | c.2081G>A p.R694Q | Missense Mutation (SNP) | VAF 131/475 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs756225782, CM071011; called by muse, mutect2, varscan2
- MS4A4A | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 46/346 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs778720872; called by muse, mutect2, varscan2
- MSANTD2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 232/284 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs534297687; called by muse, mutect2, varscan2
- MYH7 | c.5071G>A p.V1691M | Missense Mutation (SNP) | VAF 302/664 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs45464193, CM031282, COSV62518813, COSV62521627; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYL9 | c.286G>A p.G96S | Missense Mutation (SNP) | VAF 1048/1292 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs761250357; called by muse, mutect2, varscan2
- NAP1L4 | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 273/327 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1188415195; called by muse, mutect2, varscan2
- NAV3 | c.3880G>A p.G1294S | Missense Mutation (SNP) | VAF 226/432 reads (52%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.999); catalogued as rs762424798, COSV57091499, COSV99892305; called by muse, mutect2, varscan2
- NIN | c.4024C>T p.R1342W | Missense Mutation (SNP) | VAF 54/325 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs1348846883, COSV55389416; called by muse, mutect2, varscan2
- NYAP2 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 345/448 reads (77%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1361526299, COSV56007357; called by muse, mutect2, varscan2
- OAS2 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 101/226 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as rs140488386; called by muse, mutect2, varscan2
- OSBPL5 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 68/504 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867268261; called by muse, varscan2
- PCDH11X | c.3842G>T p.G1281V | Missense Mutation (SNP) | VAF 96/469 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.224); catalogued as rs1284786013, COSV100014141; called by muse, mutect2, varscan2
- PCDHGA11 | c.2131G>A p.V711M | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.185); catalogued as rs202010010; called by muse, varscan2
- PDLIM5 | c.61G>A p.G21S | Missense Mutation (SNP) | VAF 115/365 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs767631926, COSV58752152; called by muse, mutect2, varscan2
- PITRM1 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 161/340 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); catalogued as rs750724036; called by muse, mutect2, varscan2
- PKD2L2 | c.30C>T p.G10= | Splice Region (SNP) | VAF 385/385 reads (100%) | catalogued as rs201413664, COSV51796470; called by muse, mutect2, varscan2
- PTGES2 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 200/433 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as COSV52969318; called by muse, mutect2, varscan2
- RBM42 | c.279G>C p.Q93H | Missense Mutation (SNP) | VAF 159/335 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV99178853; called by muse, mutect2, varscan2
- SERPINB12 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 211/211 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs749477032, COSV54035078, COSV54035180, COSV54035271; called by muse, mutect2, varscan2
- SI | c.3883A>T p.I1295F | Missense Mutation (SNP) | VAF 123/225 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1042655616; called by muse, mutect2
- SPTBN1 | c.3533C>T p.T1178M | Missense Mutation (SNP) | VAF 152/423 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs878944023; called by muse, mutect2, varscan2
- TEX15 | c.3018dup p.A1007Sfs*3 (on ENST00000256246; = p.A1390Sfs*3 on NM_001350162.2) | Frame Shift Ins (INS) | VAF 134/436 reads (31%) | catalogued as rs753315680; called by mutect2, varscan2
- TRPM5 | c.1457G>A p.R486Q | Missense Mutation (SNP) | VAF 494/594 reads (83%) | SIFT tolerated (0.62); PolyPhen benign (0.14); catalogued as rs750376824; called by muse, mutect2, varscan2
- UPP2 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 34/416 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as rs781145130, COSV50046348; called by muse, mutect2
- WNT7A | c.292A>C p.K98Q | Missense Mutation (SNP) | VAF 166/352 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.285); catalogued as rs1244393781; called by muse, mutect2
- ZNF264 | c.1532A>G p.Y511C | Missense Mutation (SNP) | VAF 189/367 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as rs759169474; called by muse, mutect2, varscan2
- ZNF667 | c.1179G>T p.K393N | Missense Mutation (SNP) | VAF 171/352 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV52634961; called by muse, mutect2, varscan2
- ZNF787 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 103/577 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54420658; called by muse, mutect2, varscan2
- ADGB | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 125/486 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- ALKBH6 | c.166A>G p.R56G (on ENST00000252984 / NM_001297701.2; = p.R84G on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/338 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- AMY2B | c.28A>C p.I10L | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKS1B | c.1960G>C p.E654Q | Missense Mutation (SNP) | VAF 155/339 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- ARAF | c.347T>A p.L116H | Missense Mutation (SNP) | VAF 110/391 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ASPM | c.8167A>G p.R2723G | Missense Mutation (SNP) | VAF 147/258 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATXN2L | c.874C>T p.R292* | Nonsense Mutation (SNP) | VAF 135/368 reads (37%) | called by muse, mutect2, varscan2
- BCL9L | c.4018C>T p.Q1340* | Nonsense Mutation (SNP) | VAF 565/681 reads (83%) | called by muse, mutect2, varscan2
- BTBD9 | c.1322G>A p.S441N | Missense Mutation (SNP) | VAF 50/437 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CAPRIN2 | c.1388C>T p.S463F | Missense Mutation (SNP) | VAF 173/347 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- CCP110 | c.2318A>G p.K773R | Missense Mutation (SNP) | VAF 221/342 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CDH13 | c.916G>T p.G306* | Nonsense Mutation (SNP) | VAF 239/336 reads (71%) | called by muse, mutect2, varscan2
- CFAP54 | c.6178G>A p.D2060N | Missense Mutation (SNP) | VAF 208/408 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP91 | c.270G>T p.W90C | Missense Mutation (SNP) | VAF 132/332 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- CHAMP1 | c.1316T>C p.L439P | Missense Mutation (SNP) | VAF 24/794 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.12); called by muse, mutect2
- CIB3 | c.155T>A p.V52E | Missense Mutation (SNP) | VAF 191/364 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CLPTM1L | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 392/772 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DCDC2C | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 225/519 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- DIDO1 | c.509G>C p.R170T | Missense Mutation (SNP) | VAF 90/1348 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); called by muse, mutect2
- DLST | c.320A>C p.E107A | Missense Mutation (SNP) | VAF 148/314 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNAH6 | c.6553C>T p.Q2185* | Nonsense Mutation (SNP) | VAF 327/449 reads (73%) | called by muse, mutect2, varscan2
- DPP10 | c.2189T>G p.V730G | Missense Mutation (SNP) | VAF 105/274 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EBF3 | c.525A>T p.E175D | Missense Mutation (SNP) | VAF 152/323 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- EGR4 | c.339del p.D114Tfs*40 (on ENST00000545030; = p.D11Tfs*40 on NM_001965.4) | Frame Shift Del (DEL) | VAF 554/1024 reads (54%) | called by mutect2, pindel, varscan2
- FAM149A | c.1207C>T p.H403Y (on ENST00000356371 / NM_001367768.2; = p.H112Y on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/249 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- FAM169A | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 41/258 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAM228A | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 82/209 reads (39%) | called by muse, mutect2
- FAM83B | c.1479dup p.N494* | Frame Shift Ins (INS) | VAF 165/557 reads (30%) | called by mutect2, pindel, varscan2
- FOXD4L4 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 155/1200 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- FOXM1 | c.531C>G p.I177M | Missense Mutation (SNP) | VAF 216/413 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GABRA3 | c.662A>T p.Y221F | Missense Mutation (SNP) | VAF 74/311 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GRIN1 | c.740G>T p.W247L | Missense Mutation (SNP) | VAF 39/521 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- H4C4 | c.296A>C p.Y99S | Missense Mutation (SNP) | VAF 176/312 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HYAL4 | c.84del p.L29* | Frame Shift Del (DEL) | VAF 106/637 reads (17%) | called by mutect2, pindel, varscan2
- ITGAM | c.692T>A p.I231N | Missense Mutation (SNP) | VAF 155/491 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LCA5 | c.445A>C p.K149Q | Missense Mutation (SNP) | VAF 138/444 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MEF2A | c.248A>T p.D83V | Missense Mutation (SNP) | VAF 72/202 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC16 | c.31416G>T p.M10472I | Missense Mutation (SNP) | VAF 236/481 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- MUC5B | c.10309T>C p.S3437P | Missense Mutation (SNP) | VAF 220/1206 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NAPRT | c.1189-14_1200delinsT p.X397_splice | Splice Site (DEL) | VAF 185/823 reads (22%) | called by pindel, varscan2*
- NEK8 | c.1750A>T p.T584S | Missense Mutation (SNP) | VAF 53/591 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.426); called by muse, mutect2
- NFIC | c.22C>T p.L8F | Missense Mutation (SNP) | VAF 323/669 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLGN4Y | c.2324C>T p.T775M | Missense Mutation (SNP) | VAF 456/457 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- NMS | c.263T>G p.F88C | Missense Mutation (SNP) | VAF 205/593 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- PCDHB14 | c.965C>A p.T322K | Missense Mutation (SNP) | VAF 216/216 reads (100%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- PLXNA4 | c.1544G>A p.S515N | Missense Mutation (SNP) | VAF 502/639 reads (79%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PRAMEF26 | c.1074T>G p.D358E | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by mutect2, varscan2
- PROKR2 | c.599T>C p.V200A | Missense Mutation (SNP) | VAF 184/376 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0.026); called by muse, mutect2
- PTPRU | c.1196A>T p.Q399L | Missense Mutation (SNP) | VAF 188/407 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- RNF217 | c.1074dup p.G359Rfs*27 (on ENST00000521654 / NM_001286398.2; = p.G67Rfs*27 on NM_152553.5) | Frame Shift Ins (INS) | VAF 315/659 reads (48%) | called by mutect2, pindel, varscan2
- SCN7A | c.3521T>G p.I1174S | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- SLC9A9 | c.1273C>T p.Q425* | Nonsense Mutation (SNP) | VAF 130/269 reads (48%) | called by muse, mutect2, varscan2
- SLIT1 | c.386T>A p.F129Y | Missense Mutation (SNP) | VAF 249/523 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TDRD3 | c.730C>G p.L244V | Missense Mutation (SNP) | VAF 78/304 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TENM4 | c.1694A>G p.N565S | Missense Mutation (SNP) | VAF 60/378 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRAJ47 | c.49G>C p.V17L | Missense Mutation (SNP) | VAF 276/276 reads (100%) | called by muse, mutect2, varscan2
- UNC13C | c.3527A>C p.K1176T | Missense Mutation (SNP) | VAF 234/234 reads (100%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- UNC80 | c.8081del p.L2694* | Frame Shift Del (DEL) | VAF 101/312 reads (32%) | called by mutect2, pindel, varscan2
- UTP11 | c.730A>T p.I244F | Missense Mutation (SNP) | VAF 148/310 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- VCAN | c.1148C>A p.P383H | Missense Mutation (SNP) | VAF 280/280 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- ZNF536 | c.1712C>A p.A571E | Missense Mutation (SNP) | VAF 183/390 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- ZNF722P | c.215A>T p.K72I | Missense Mutation (SNP) | VAF 98/426 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- AHNAK | c.93C>T p.G31= | Silent (SNP) | VAF 92/680 reads (14%) | catalogued as rs770685879, COSV57230938; called by muse, mutect2, varscan2
- ANKRD35 | c.528C>T p.G176= | Silent (SNP) | VAF 216/506 reads (43%) | catalogued as rs201831600, COSV62910848; called by muse, mutect2, varscan2
- BAAT | c.1008C>T p.H336= | Silent (SNP) | VAF 189/444 reads (43%) | catalogued as rs144681311; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CARMIL3 | c.1077C>T p.F359= | Silent (SNP) | VAF 235/235 reads (100%) | called by muse, mutect2, varscan2
- CEP85L | c.261T>A p.S87= | Silent (SNP) | VAF 34/296 reads (11%) | catalogued as rs1413606561; called by muse, mutect2, varscan2
- CHMP2B | c.465C>T p.D155= | Silent (SNP) | VAF 95/188 reads (51%) | catalogued as rs758354665, COSV55461442; called by muse, mutect2, varscan2
- ELAC2 | c.1644C>T p.H548= | Silent (SNP) | VAF 50/351 reads (14%) | catalogued as rs778683685, COSV61647937; called by muse, mutect2, varscan2
- ELFN1 | c.96C>A p.I32= | Silent (SNP) | VAF 40/698 reads (6%) | called by muse, mutect2
- GSX1 | c.48C>T p.G16= | Silent (SNP) | VAF 166/854 reads (19%) | called by muse, mutect2, varscan2
- HOXC10 | c.522C>T p.F174= | Silent (SNP) | VAF 293/576 reads (51%) | called by muse, mutect2, varscan2
- IFT88 | c.177T>A p.P59= (on ENST00000319980 / NM_001318493.2; = p.P50= on NM_006531.5 and 9 other RefSeq transcripts) | Silent (SNP) | VAF 88/403 reads (22%) | called by muse, mutect2, varscan2
- IQSEC1 | c.822G>A p.A274= | Silent (SNP) | VAF 245/548 reads (45%) | catalogued as rs757948728; called by muse, mutect2, varscan2
- JMJD8 | c.525G>T p.G175= | Silent (SNP) | VAF 164/490 reads (33%) | called by muse, mutect2, varscan2
- KLHL4 | c.1020T>C p.P340= | Silent (SNP) | VAF 94/383 reads (25%) | called by muse, mutect2, varscan2
- LAMA1 | c.3111G>A p.A1037= | Silent (SNP) | VAF 159/335 reads (47%) | catalogued as rs200710797, COSV67533149; called by muse, mutect2
- LGSN | c.834A>T p.S278= | Silent (SNP) | VAF 127/371 reads (34%) | called by muse, mutect2, varscan2
- MTHFR | c.1887C>T p.D629= | Silent (SNP) | VAF 72/522 reads (14%) | catalogued as rs780005836; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO5B | c.2380C>T p.L794= | Silent (SNP) | VAF 59/240 reads (25%) | catalogued as COSV53223749, COSV99546407; called by muse, mutect2, varscan2
- NKAP | c.726G>A p.K242= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV65056722; called by muse, mutect2
- NRXN3 | c.1581T>A p.I527= | Silent (SNP) | VAF 267/477 reads (56%) | called by muse, mutect2, varscan2
- OR2T29 | c.75C>G p.S25= | Silent (SNP) | VAF 71/240 reads (30%) | called by muse, mutect2
- OR2T5 | c.75C>G p.S25= | Silent (SNP) | VAF 96/462 reads (21%) | catalogued as COSV100822165; called by muse, mutect2, varscan2
- OR4C16 | c.667C>T p.L223= | Silent (SNP) | VAF 90/404 reads (22%) | catalogued as rs1357177544; called by muse, mutect2, varscan2
- OR51I2 | c.738G>A p.L246= | Silent (SNP) | VAF 59/425 reads (14%) | catalogued as rs1320921070, COSV58299325; called by muse, mutect2, varscan2
- OR5M1 | c.282C>T p.Y94= | Silent (SNP) | VAF 84/466 reads (18%) | catalogued as rs371477399; called by muse, mutect2, varscan2
- PPP1R3A | c.513C>T p.D171= | Silent (SNP) | VAF 73/358 reads (20%) | catalogued as rs1412674633; called by muse, mutect2, varscan2
- PREPL | c.66C>T p.C22= | Silent (SNP) | VAF 112/313 reads (36%) | called by muse, mutect2, varscan2
- RAMP1 | c.381C>A p.I127= | Silent (SNP) | VAF 520/716 reads (73%) | called by muse, mutect2, varscan2
- ROBO1 | c.2409A>G p.E803= | Silent (SNP) | VAF 40/259 reads (15%) | called by muse, mutect2, varscan2
- SLC3A1 | c.1155C>T p.A385= | Silent (SNP) | VAF 211/594 reads (36%) | catalogued as rs1220291346; called by muse, mutect2, varscan2
- SYNE1 | c.3897G>A p.A1299= (on ENST00000367255 / NM_182961.4; = p.A1306= on NM_033071.3) | Silent (SNP) | VAF 370/609 reads (61%) | catalogued as COSV55034127; called by muse, mutect2, varscan2
- TPST2 | c.435T>A p.I145= | Silent (SNP) | VAF 271/603 reads (45%) | called by muse, mutect2, varscan2
- TTN | c.22035T>A p.S7345= (on ENST00000591111; = p.S6418= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 162/474 reads (34%) | called by muse, mutect2, varscan2
- TTN | c.11592C>T p.T3864= (on ENST00000591111; = p.T3818= on NM_003319.4) | Silent (SNP) | VAF 125/406 reads (31%) | catalogued as rs764856949, COSV59970021, COSV60085742; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF3 | c.354G>A p.K118= | Silent (SNP) | VAF 455/596 reads (76%) | catalogued as rs1379486662; called by muse, mutect2, varscan2
- ZNF543 | c.438G>T p.L146= | Silent (SNP) | VAF 29/571 reads (5%) | called by muse, mutect2
- ZNF804B | c.2547T>A p.T849= | Silent (SNP) | VAF 103/480 reads (21%) | catalogued as COSV100303891, COSV60819606; called by muse, mutect2, varscan2
- IKZF2 | c.139+58T>C | Intron (SNP) | VAF 49/439 reads (11%) | called by muse, varscan2
- JMJD4 | c.692+43G>A | Intron (SNP) | VAF 343/709 reads (48%) | called by muse, mutect2, varscan2
- PIEZO2 | c.2492+4437C>T | Intron (SNP) | VAF 170/332 reads (51%) | catalogued as rs907548476; called by muse, mutect2, varscan2
- REXO1L1P | n.1491T>A | RNA (SNP) | VAF 131/4082 reads (3%) | called by muse, mutect2
- SH3KBP1 | c.520+609G>C | Intron (SNP) | VAF 185/185 reads (100%) | called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827960 C>A | 3'Flank (SNP) | VAF 98/398 reads (25%) | catalogued as COSV59425810; called by muse, mutect2, varscan2
